Somatic mutation profile of tumor specimen TCGA-QR-A700-01A (aliquot TCGA-QR-A700-01A-11D-A35D-08) from TCGA case TCGA-QR-A700, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 67.7 years (24,734 days).
Specimen TCGA-QR-A700-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca2f7f9a-65cf-4c1a-868c-c5c424c9d47c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A700-10A (Blood Derived Normal), aliquot TCGA-QR-A700-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89a8592d-b28e-4272-8be5-59e293611bb4

The open-access MAF lists 41 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 29, Silent 5, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYTIP | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.122); catalogued as rs371636217; called by muse, mutect2
- GPR149 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.634); catalogued as rs906925874, COSV67666015; called by muse, mutect2, varscan2
- JADE2 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs757432320; called by muse, mutect2, varscan2
- METTL1 | c.496T>G p.F166V | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1440131546; called by muse, mutect2, varscan2
- PGLYRP2 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs1451268785; called by muse, mutect2, varscan2
- PNISR | c.902A>C p.E301A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV100984336; called by muse, mutect2, varscan2
- POLR1B | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV54504292; called by muse, mutect2
- RC3H1 | c.827A>G p.Y276C | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1284341672; called by muse, mutect2, varscan2
- SBF1 | c.1520G>T p.R507L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs1294559270; called by muse, mutect2
- SERPINF1 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54616197; called by muse, mutect2, varscan2
- SLC9A4 | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 23/111 reads (21%) | catalogued as rs754266683, COSV54829700; called by muse, mutect2, varscan2
- URGCP | c.1817T>G p.L606R (on ENST00000453200 / NM_001077663.3; = p.L597R on NM_017920.4) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV99788172; called by muse, mutect2, varscan2
- AKAP4 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGEF12 | c.3671C>T p.T1224I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- BCAR1 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- C2CD3 | c.5361G>T p.L1787= | Splice Region (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- CCDC121 | c.757_800del p.Q253Sfs*9 | Frame Shift Del (DEL) | VAF 10/145 reads (7%) | called by mutect2, pindel
- ELOA | c.1852A>T p.I618L | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- GCSAML | c.341G>T p.R114M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GIT2 | c.1439C>G p.T480R (on ENST00000355312 / NM_057169.5; = p.T432R on NM_014776.5) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GRIA2 | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 77/114 reads (68%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC25 | c.14T>G p.L5R | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); called by muse, mutect2
- MXRA5 | c.4331C>A p.S1444* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- NYNRIN | c.2189C>T p.T730I | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- OR4K1 | c.377T>C p.I126T | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- OR51B4 | c.150T>A p.D50E | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ORC5 | c.878-1G>A p.X293_splice | Splice Site (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- PCDHB12 | c.1933A>G p.K645E | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- PNPLA8 | c.1232G>T p.R411L | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- POLE | c.4133G>A p.G1378D | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SETBP1 | c.3382A>G p.M1128V | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGO1 | c.1173T>A p.N391K | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- VAMP3 | c.219G>A p.W73* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- WASHC4 | c.2507A>G p.N836S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ZFHX4 | c.4132T>G p.L1378V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZSCAN21 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AGPAT3 | c.1035G>A p.V345= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs1306289648, COSV99377415; called by muse, mutect2, varscan2
- DCAF4L2 | c.117C>T p.F39= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs779092689, COSV60476339; called by muse, mutect2, varscan2
- MARCHF7 | c.978C>T p.S326= | Silent (SNP) | VAF 6/63 reads (10%) | called by muse, mutect2
- MAS1L | c.882C>A p.T294= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- SCNN1B | c.645G>A p.L215= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV56303520; called by muse, mutect2, varscan2
